TCGA case TCGA-DD-A115 — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/45b566d7-f120-471c-a94a-be7936889f2d

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Dead; Days to death: 2,542 days (7.0 years).

Diagnoses (2)
1. Hepatocellular carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 53.9 years (19,697 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Clinical Trial Agent; Days to treatment start: 502 days (1.4 years); Days to treatment end: 841 days (2.3 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Ablation, Ethanol Injection; Days to treatment start: 855 days (2.3 years); Number of cycles: 1.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 1,121 days (3.1 years); Embolic agent: Other.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 1,170 days (3.2 years).
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 1,281 days (3.5 years); Embolic agent: Other.
   Treatment given: Treatment type: Chemoembolization; Therapeutic agents: Doxorubicin; Days to treatment start: 1,477 days (4.0 years); Embolic agent: Other.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Hepatocellular carcinoma, NOS), site: Liver. Age at diagnosis: 55.2 years (20,166 days); Days to diagnosis: 469 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Ablation or Embolization, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 469 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Liver; Days to recurrence: 469 days (1.3 years).
- Days to follow up: 2,542 days (7.0 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- Albumin 4.1 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Platelets 337 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.
- Creatinine 1.1 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1.2].
- Alpha Fetoprotein 10 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 6].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 168 cm; BMI: 28.
- Timepoint category: Prior to Diagnosis; Risk factors: Alcohol Consumption / Tobacco, Smoking; Viral hepatitis serology tests: Hepatitis B Surface Antigen / HBV Surface Antibody / HBV Core Antibody.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DD-A115-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 230 mg.
  Slide TCGA-DD-A115-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 4; Percent necrosis: 0; Percent stromal cells: 6; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-DD-A115-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 3; Percent necrosis: 0; Percent stromal cells: 7; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DD-A115-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DD-A115-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-DD-A115-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-DD-A115-11A-01-TSA: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 90; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Extended Lobectomy.
- Viral hepatitis serologies: Viral hepatitis serology: Hepatitis B Surface Antigen; Viral hepatitis serology: HBV Surface Antibody; Viral hepatitis serology: HBV Core Antibody.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.
- Drug treatment: Clinical trial drug classification: Phase II.
- Ablations, Ablation, Ablation treatments: Ablation performed indicator: Yes.
- Ablations, Ablation, Ablation treatments, Ablation treatment: Ablation type: alcohol ablation; Treatment cycles count: 1.
- Ablations, Ablation, Embolization treatments: Embolization performed indicator: Yes.
- Ablations, Ablation, Embolization treatments, Embolization treatment 1: Embolizing agent utilized: Doxorubicin, mitomycin, and Ivalon.
- Ablations, Ablation, Embolization treatments, Embolization treatment 3: Embolizing agent utilized: chemoembolic mixture.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,542 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,542 days; disease-free interval: event (new tumor event after initially disease-free), 469 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 469 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DD-A115-01A-11D-A12Y-01): tumor purity 0.66, ploidy 3.69, whole-genome doublings 1.
